Gene-level copy-number profile of tumor specimen TCGA-HZ-A9TJ-06A from TCGA case TCGA-HZ-A9TJ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 70.8 years (25,849 days).
Specimen TCGA-HZ-A9TJ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.c12fa6d5-ef17-4ac7-af35-547936b23537.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HZ-A9TJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 406 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/33c72b66-ec58-4c14-adf8-22f2601ae666

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,568; copy number 1: 2,274; copy number 2: 10,647; copy number 3: 26,199; copy number 4: 9,523; copy number 5: 3,039; copy number 6: 5,429; copy number 7: 373; copy number 8: 665; copy number 9: 8; copy number 10: 204; copy number 11: 96; copy number 12: 26; copy number 13: 136; copy number 15: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HZ-A9TJ-06A-11D-A40V-01): tumor purity 0.49, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 19 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:22,812,628–22,833,430, 2 genes: TOMM7, AC005682.2.
- chr9:60,914,407–61,662,690, 17 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, BX005040.4, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,538 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:202,348,699–204,685,738, 82 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:211,258,377–213,274,774, 61 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr3:143,855,739–145,685,092, 6 genes, copy number 7: AC107421.1, DIPK2A, RNA5SP144, AC011592.1, LARP7P4, GM2AP1.
- chr3:160,495,007–161,253,532, 11 genes, copy number 7 (within-gene range 4–7): KPNA4, SCARNA7, KRT8P12, RPL6P8, ARL14, SNORA72, AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1.
- chr3:166,293,756–173,336,965, 118 genes, copy number 7 (broad region; genes not listed).
- chr7:70,972–22,773,993, 352 genes, copy number 7–8 (within-gene range 7–17) (broad region; genes not listed).
- chr7:22,854,126–41,133,507, 374 genes, copy number 8 (broad region; genes not listed).
- chr7:52,891,837–53,188,938, 4 genes, copy number 7: SGO1P2, AC074397.1, POM121L12, HAUS6P1.
- chr7:63,011,463–68,724,048, 208 genes, copy number 9–13 (broad region; genes not listed).
- chr7:128,617,865–134,066,589, 129 genes, copy number 10–15 (within-gene range 6–15) (broad region; genes not listed).
- chr7:134,127,299–137,343,774, 50 genes, copy number 10–11 (within-gene range 6–11): LRGUK, AC008154.2, SLC35B4, AC008154.1, AC009275.1, AKR1B1, AKR1B10, AKR1B15, BPGM, AC009276.1, TUBB3P2, CALD1, AC083870.1, AGBL3, CYREN, RNF14P4, TMEM140, AC083862.1, AC083862.2, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205, AC093107.2, AC093107.1, STMP1, RNU6-1154P, SLC13A4, AC091736.1, FAM180A, AC015987.1, MTPN, RNU6-223P, AC024084.1, AC078845.1, Y_RNA, AC009784.1, ZP3P2, AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51, AC009517.1, PTN, SNORD81.
- chr7:142,778,642–143,523,449, 55 genes, copy number 10 (within-gene range 5–10): WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2, TRBV30, EPHB6, TRPV6, AC245427.1, AC245427.2, TRPV5, LLCFC1, KEL, OR9A2, OR9P1P, OR6V1, OR6W1P, PIP, TAS2R39, AC073342.1, TAS2R40, AC073342.2, GSTK1, TMEM139-AS1, TMEM139, CASP2, RN7SL535P, RN7SL481P, HINT1P1, CLCN1, FAM131B, AC093673.2, AC093673.1, ZYX, MIR6892, EPHA1, EPHA1-AS1, TAS2R62P, TAS2R60, TAS2R41, OR2R1P, OR10AC1.
- chr18:20,946,906–23,026,488, 50 genes, copy number 7–11: ROCK1, AC022795.1, RNU6-120P, EXOGP1, AC022809.1, GREB1L, AC015878.2, AC015878.1, AC011774.1, ESCO1, SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA.
- chr18:24,500,399–26,657,401, 32 genes, copy number 10–11: AC007922.4, AC007922.3, EIF4A3P1, LINC01915, RAC1P1, PPIAP57, AC018697.1, LINC01894, WBP2P1, AC104961.1, ZNF521, AC105114.2, AC105114.1, AC110603.1, RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P.
- chr18:26,685,954–26,865,771, 6 genes, copy number 11: AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4.

Autosomal genes at a single copy (total copy number 1): 913. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
